Surgical pathology report (de-identified scan), TCGA case TCGA-VB-A8QN, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Global BioClinical - Georgia, specimen TCGA-VB-A8QN-01A (Primary Tumor).

DEPARTMENT OF PATHOLOGY

Patient:

received

Sent out:

Sex: male

Date of birth:

ICD-O-3
Lymphoma, diffuse large B-cell 9680/3
Site Stomach NOS C16.9
9/25/30/14

Clinical diagnosis: gastric cancer vs. lymphoma? With metastasis in liver.

Macroscopy: the stomach tumor 10x8 cm with ulceration and invasion to muscular layer. The III segment of liver with tumor 4x3 cm. 8 lymph nodes from omentum minor.

Microscopy: the serous of gastric with ulceration and infiltration by medium and large cells of lymphoid origin. In III segment of liver and lymph nodes from omentum minor there are proliferations of the same cells.

By immunohistochemistry cells are positive for CD20 and Ki-67=60%.

Conclusion: Diffuse large cell lymphoma of gastric with involvement of lymph nodes of omentum minor and III segment of liver.

Head of pathology department

Pathologist:

Diagnosis Discrepancy	W 9/16/13	☒

Source: NCI Genomic Data Commons file 867b9d53-686b-4e1e-bf6e-de593f9ca390 (TCGA-VB-A8QN.A661F75B-6FD2-4294-8103-969308EFF4EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).